Somatic mutation profile of tumor specimen C3N-00516-01 (aliquot CPT0078090007) from CPTAC case C3N-00516, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 68.9 years (25,164 days).
Specimen C3N-00516-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19d5c901-f880-40eb-bd6a-00e9f8bc95a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00516-31 (Blood Derived Normal), aliquot CPT0078150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7df524a0-ce80-4fcc-929e-07fd5ad4bad1

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 7, Intron 4, RNA 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 100/397 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 114/435 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- B4GALNT4 | c.1657G>A p.V553I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1430980375; called by muse, mutect2, varscan2
- COL13A1 | c.1736C>T p.P579L (on ENST00000398978 / NM_001130103.2; = p.P507L on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs766119482; called by muse, mutect2, varscan2
- CSMD1 | c.5309C>T p.P1770L (on ENST00000520002; = p.P1769L on NM_033225.6) | Missense Mutation (SNP) | VAF 80/434 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771790436; called by muse, mutect2, varscan2
- DSCAM | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1432629129, COSV68648785; called by muse, mutect2
- FBXW5 | c.634dup p.I212Nfs*53 | Frame Shift Ins (INS) | VAF 65/212 reads (31%) | catalogued as rs762193986; called by mutect2, pindel, varscan2
- GPR158 | c.3322C>T p.R1108C | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs372238950, COSV66267514; called by muse, mutect2, varscan2
- JAG2 | c.3016C>T p.R1006W | Missense Mutation (SNP) | VAF 40/416 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs1358299413; called by muse, mutect2
- LUM | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 22/269 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57129387; called by muse, mutect2
- MYC | c.665C>G p.S222C (on ENST00000377970; = p.S237C on NM_002467.6) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV52373051; called by muse, mutect2, varscan2
- MYO1F | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs758097575, COSV57792161; called by muse, mutect2
- PIGQ | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs752541286, COSV50314907; called by muse, mutect2, varscan2
- RASGRP4 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 69/264 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769519232, COSV53039354; called by muse, mutect2, varscan2
- SCUBE2 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 24/293 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs370871651; called by muse, mutect2
- SMARCA1 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1318171945, COSV100946432; called by muse, mutect2, varscan2
- SNTG2 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 113/472 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as rs768494785; called by muse, mutect2, varscan2
- TRIM42 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 32/575 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1250313209, COSV53883465; called by muse, mutect2
- ZNF33B | c.2009G>A p.C670Y | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369377643; called by muse, mutect2
- ARFGEF2 | c.4536A>C p.L1512F | Missense Mutation (SNP) | VAF 30/502 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- HEG1 | c.2822C>T p.S941L | Missense Mutation (SNP) | VAF 38/361 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- KCNJ9 | c.439T>G p.S147A | Missense Mutation (SNP) | VAF 72/377 reads (19%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- KRT23 | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MRI1 | c.557G>C p.R186P | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTAP | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR1M1 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 29/289 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2
- PGR | c.1790G>A p.G597E | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHM3 | c.1264G>T p.D422Y | Missense Mutation (SNP) | VAF 64/296 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC5A4 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 105/456 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TRIO | c.6301G>T p.V2101L | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ZNF226 | c.1766G>A p.C589Y | Missense Mutation (SNP) | VAF 72/248 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BMP5 | c.138C>T p.H46= | Silent (SNP) | VAF 44/504 reads (9%) | catalogued as rs773535817, COSV100895669; called by muse, mutect2
- CAPN3 | c.1077G>A p.P359= | Silent (SNP) | VAF 83/357 reads (23%) | catalogued as rs759384108, COSV100532508; called by muse, mutect2, varscan2
- DGKZ | c.3009C>T p.G1003= (on ENST00000454345 / NM_001105540.2; = p.G815= on NM_003646.4) | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs148565335; called by muse, mutect2, varscan2
- GABBR1 | c.2034C>T p.Y678= | Silent (SNP) | VAF 24/300 reads (8%) | catalogued as rs758589287, COSV63541979; called by muse, mutect2
- GID8 | c.165C>T p.I55= | Silent (SNP) | VAF 40/197 reads (20%) | catalogued as rs965129217; called by muse, mutect2, varscan2
- RASAL1 | c.894G>A p.L298= | Silent (SNP) | VAF 11/218 reads (5%) | catalogued as COSV55655439; called by muse, mutect2
- THSD7B | c.3891C>T p.T1297= (on ENST00000272643; = p.T1295= on NM_001316349.2) | Silent (SNP) | VAF 14/252 reads (6%) | called by muse, mutect2
- CCDC7 | c.1454+2595G>A | Intron (SNP) | VAF 24/139 reads (17%) | called by muse, mutect2, varscan2
- CMAHP | n.1745T>C | RNA (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- ECM1 | c.385+35C>T | Intron (SNP) | VAF 14/280 reads (5%) | called by muse, mutect2
- H2BP2 | n.1061+1853C>A | Intron (SNP) | VAF 30/430 reads (7%) | called by muse, mutect2
- HSP90AA4P | n.1732dup | RNA (INS) | VAF 24/122 reads (20%) | catalogued as rs70944383; called by mutect2, pindel, varscan2
- MICAL3 | c.2241+1577_2241+1578insG | Intron (INS) | VAF 10/70 reads (14%) | called by mutect2, pindel*
- SPATA31C1 | n.2324A>T | RNA (SNP) | VAF 144/491 reads (29%) | called by muse, mutect2, varscan2
